CCDI case PBCMNI — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/a9fde69b-85a4-4e07-8a66-1669b9a1906d

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Rhabdomyoma, NOS: ICD-O-3 morphology code: 8900/0; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; Age at diagnosis: 6.5 years (2,367 days).

Biospecimens (3 samples)
- Sample 0DVPN2: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DVPOK: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DVPP4: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
